Somatic mutation profile of tumor specimen TCGA-C5-A2LT-01A (aliquot TCGA-C5-A2LT-01A-11D-A18J-09) from TCGA case TCGA-C5-A2LT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 38.2 years (13,966 days).
Specimen TCGA-C5-A2LT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afe2d5d4-c79f-47c3-a7c9-f5e64dc1ef12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A2LT-10A (Blood Derived Normal), aliquot TCGA-C5-A2LT-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9de34044-247b-41a7-89c7-f2a8fca3313e

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 12, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.3205G>C p.E1069Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); catalogued as rs766340916, COSV51661148; called by muse, mutect2, varscan2
- ATP12A | c.342dup p.F115Vfs*64 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs35191129; called by mutect2, varscan2
- CACNA1E | c.6472C>T p.Q2158* (on ENST00000367573 / NM_001205293.3; = p.Q2115* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV62383648; called by muse, mutect2, varscan2
- CALD1 | c.1639G>A p.E547K (on ENST00000361675 / NM_033138.4; = p.E292K on NM_004342.7) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1317987842; called by muse, mutect2, varscan2
- CASR | c.2456G>A p.R819H (on ENST00000490131; = p.R896H on NM_000388.4) | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs773552397, CM068561, COSV56135769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN2A | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV58702765; called by muse, mutect2, varscan2
- CTSG | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.181); catalogued as rs1310147398; called by muse, varscan2
- DNAH11 | c.6093A>C p.L2031F | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60977373; called by muse, mutect2, varscan2
- ELAPOR2 | c.2755G>T p.A919S (on ENST00000450689 / NM_001142749.3; = p.A752S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1397750250; called by muse, mutect2, varscan2
- FAT1 | c.13670C>A p.S4557Y | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101499333, COSV101499527; called by muse, mutect2
- KCNH8 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as rs755303397, COSV60463215; called by muse, mutect2, varscan2
- LRP1B | c.9557G>A p.R3186H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs780939740, COSV104431406; called by muse, varscan2
- MGAT3 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.235); catalogued as rs1403786617, COSV57867166; called by muse, mutect2, varscan2
- PKD1 | c.7405C>T p.R2469C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs367918229; called by muse, mutect2, varscan2
- SLC6A4 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1196104137, COSV55567440; called by muse, mutect2, varscan2
- THAP3 | c.621G>T p.Q207H (on ENST00000054650 / NM_001195753.1; = p.Q206H on NM_001195752.1) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV99275678; called by muse, mutect2
- TMEM200A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1416618515, COSV51648874; called by muse, mutect2, varscan2
- TRIM24 | c.2718+1G>A p.X906_splice (on ENST00000343526 / NM_015905.3; = p.X872_splice on NM_003852.4) | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100630952; called by muse, mutect2, varscan2
- ALG13 | c.2836G>T p.A946S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- FAM155A | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, varscan2
- LAMA5 | c.7753C>T p.L2585F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MUC16 | c.20660C>A p.A6887E | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PDE6C | c.1023C>G p.H341Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PRMT5 | c.653T>G p.I218S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PSMD2 | c.1908C>A p.D636E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAMD15 | c.1242G>C p.E414D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); called by muse, mutect2
- TGFBR3 | c.788T>G p.L263R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZNF185 | c.1286G>T p.R429I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ZNF658 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD55 | c.1488T>C p.S496= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1183471652; called by muse, mutect2, varscan2
- CDRT15 | c.423G>A p.E141= | Silent (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
- CEP290 | c.4402C>T p.L1468= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs1565838540, COSV58350775; called by muse, mutect2, varscan2
- FNDC1 | c.1845G>A p.S615= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1217396894, COSV51941689; called by mutect2, varscan2
- GPC6 | c.1428C>T p.N476= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs146868653; called by muse, varscan2
- KCNJ13 | c.549C>A p.G183= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- NAV3 | c.582G>A p.Q194= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99891682; called by muse, mutect2, varscan2
- OFD1 | c.1926C>T p.A642= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs757775981; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4C13 | c.642C>T p.V214= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV73648896; called by muse, mutect2, varscan2
- PRDM10 | c.1212G>T p.R404= | Silent (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- RABGAP1 | c.78C>G p.V26= | Silent (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- TGIF2LX | c.591C>T p.V197= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV99383332; called by muse, mutect2, varscan2
- MIR222 | n.60G>A | RNA (SNP) | VAF 29/102 reads (28%) | catalogued as rs72631825; called by muse, mutect2, varscan2
